Somatic mutation profile of tumor specimen TCGA-CV-6939-01A (aliquot TCGA-CV-6939-01A-11D-1912-08) from TCGA case TCGA-CV-6939, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 60.1 years (21,947 days).
Specimen TCGA-CV-6939-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6dd18ed0-a812-4640-bc0b-bde29d5032d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-6939-10A (Blood Derived Normal), aliquot TCGA-CV-6939-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/833934ed-49e4-4206-b1f1-c3982cc37f61

The open-access MAF lists 43 somatic variants for this specimen: 32 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 10, Frame Shift Del 4, Nonsense Mutation 2, 5'UTR 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF1 | c.1369C>G p.L457V | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.108); catalogued as COSV57119837; called by muse, mutect2, varscan2
- ALG12 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 8/92 reads (9%) | PolyPhen possibly damaging (0.657); catalogued as rs911437496, COSV58207097; called by muse, mutect2
- ALOX15B | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV101205573; called by muse, mutect2, varscan2
- CC2D2A | c.2539G>A p.D847N | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.43); catalogued as COSV101052676; called by muse, mutect2
- CDH19 | c.2029G>T p.E677* | Nonsense Mutation (SNP) | VAF 47/180 reads (26%) | catalogued as COSV100051038, COSV100051218; called by muse, mutect2, varscan2
- CDK5RAP1 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1454835648, COSV100211895; called by muse, mutect2
- CYP4A11 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as rs769643633, COSV100152229; called by muse, mutect2, varscan2
- GDI1 | c.304T>G p.F102V | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100870656; called by muse, mutect2, varscan2
- GFRA1 | c.641G>A p.C214Y | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100815531, COSV100815848; called by muse, mutect2, varscan2
- HECW1 | c.1345A>C p.I449L | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV101222968; called by muse, mutect2
- LAMC2 | c.1214C>G p.A405G | Missense Mutation (SNP) | VAF 19/316 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.721); catalogued as COSV99917157; called by muse, mutect2
- LRP2 | c.3611C>T p.T1204I | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV99786882; called by muse, mutect2, varscan2
- MED12 | c.396+2T>G p.X132_splice | Splice Site (SNP) | VAF 4/13 reads (31%) | catalogued as COSV100376555; called by muse, mutect2, varscan2
- MROH7 | c.1843C>T p.L615F | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs756649665, COSV100273072; called by muse, mutect2, varscan2
- MTR | c.2407G>A p.V803I | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.764); catalogued as COSV100855262; called by muse, mutect2, varscan2
- MTR | c.2408T>A p.V803D | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100855263; called by muse, mutect2, varscan2
- MYLPF | c.112G>T p.D38Y | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100362991; called by muse, mutect2, varscan2
- MYO15A | c.7804G>A p.V2602M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV99231486; called by muse, mutect2
- NEDD4 | c.3500A>C p.Q1167P (on ENST00000508342 / NM_001284338.1; = p.Q748P on NM_006154.4) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100163409; called by muse, mutect2
- PIK3R3 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs746011332, COSV53107616; called by muse, mutect2, varscan2
- POMT1 | c.1013C>G p.P338R | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV100586147, COSV100586450; called by muse, mutect2, varscan2
- PRPF6 | c.2531T>C p.L844P | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99411523; called by muse, mutect2, varscan2
- SH3RF3 | c.1811G>C p.R604P | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100512457; called by muse, mutect2, varscan2
- TAF1L | c.4189C>T p.R1397C | Missense Mutation (SNP) | VAF 53/298 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs528038779, COSV54261079; called by muse, mutect2, varscan2
- TBCEL | c.1258G>C p.E420Q | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as COSV99411970; called by muse, mutect2, varscan2
- TRAF3 | c.960G>A p.Q320= | Splice Region (SNP) | VAF 3/20 reads (15%) | catalogued as COSV100693432, COSV100693487; called by muse, mutect2
- TXNIP | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs1553766565, COSV100997262; called by muse, mutect2, varscan2
- FMN1 | c.3408_3424delinsA p.N1136Kfs*4 (on ENST00000616417 / NM_001277313.2; = p.N913Kfs*4 on NM_001103184.4) | Frame Shift Del (DEL) | VAF 7/54 reads (13%) | called by pindel, varscan2*
- ID3 | c.253del p.A85Pfs*41 | Frame Shift Del (DEL) | VAF 35/124 reads (28%) | called by mutect2, pindel, varscan2
- IQGAP1 | c.4802_4804del p.F1601_E1602delins* | Nonsense Mutation (DEL) | VAF 10/39 reads (26%) | called by mutect2, pindel, varscan2
- RB1 | c.2300del p.N767Ifs*43 | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | called by mutect2, pindel, varscan2
- SLITRK5 | c.1648del p.D550Tfs*3 | Frame Shift Del (DEL) | VAF 34/160 reads (21%) | called by mutect2, pindel, varscan2
- CASZ1 | c.207T>A p.P69= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as COSV100680866; called by muse, varscan2
- FCN1 | c.780C>T p.D260= | Silent (SNP) | VAF 63/356 reads (18%) | catalogued as COSV100878834; called by muse, mutect2, varscan2
- GEMIN5 | c.1710G>A p.L570= | Silent (SNP) | VAF 12/164 reads (7%) | catalogued as rs746581979, COSV99593670; called by muse, mutect2
- KCTD19 | c.750C>G p.A250= | Silent (SNP) | VAF 19/228 reads (8%) | catalogued as COSV100430702; called by muse, mutect2
- NUMA1 | c.3357C>T p.G1119= | Silent (SNP) | VAF 34/101 reads (34%) | catalogued as COSV100705869; called by muse, mutect2, varscan2
- PAOX | c.750C>A p.I250= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV99529705; called by muse, mutect2, varscan2
- PIK3R4 | c.987C>G p.A329= | Silent (SNP) | VAF 29/162 reads (18%) | catalogued as COSV100768276; called by muse, mutect2, varscan2
- SLC9A9 | c.1813C>T p.L605= | Silent (SNP) | VAF 37/126 reads (29%) | catalogued as COSV100339709; called by muse, mutect2, varscan2
- TERF1 | c.273C>T p.R91= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV99401000; called by muse, mutect2, varscan2
- ZNF180 | c.708T>C p.H236= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as rs1368687396, COSV99659646; called by muse, mutect2, varscan2
- CHRNB3 | c.-1G>A | 5'UTR (SNP) | VAF 15/85 reads (18%) | catalogued as rs746346995, COSV99250899; called by muse, mutect2, varscan2
